Surgical pathology report (de-identified scan), TCGA case TCGA-06-0650, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0650-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

TCGA-06-0650

CLINICAL HISTORY

[REDACTED] with recent onset seizures has right frontal heterogeneously intra axial tumor, with hemorrhage, vasogenic edema, and mass effect..

OPERATIVE DIAGNOSES

Not Given

Operation/Specimen: A: Brain, right frontal tumor, excision biopsy
B: Brain, right frontal tumor, excision biopsy

PATHOLOGICAL DIAGNOSIS:

A and B. Brain, right frontal, excision: Glioblastoma. MIB-1 proliferation index: 30%.
See Comment.

COMMENT

The specimens contain portions of a neoplastic proliferation of small glial cells, with nuclear anaplasia, mitotic figures, a very high proliferation index, microvascular cellular proliferation and necrosis, and zones of tumor necrosis with pseudopalisading. There are zones of hemorrhage, with prominent thrombosis of vessels.

The phenotype of this high histological grade glioma (WHO grade IV) is predominantly astrocytic. These small cell glioblastomas are difficult to tell apart from malignant oligodendrogliomas. Determining the LOH status of this patient may better characterize the neoplasm.

PROCEDURES/ADDENDA

MGMT Promoter Methylation

Date Ordered: [REDACTED]

Date Reported: [REDACTED]

Interpretation

POSITIVE - Methylated MGMT promoter is detected.

[page 2 of 3]
Results--Comments

Testing was done on block

TEST DESCRIPTION: Bisulfite treatment of DNA followed by PCR amplification of both methylated and unmethylated MGMT promoter sequences, with products detected by gel electrophoresis.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

[REDACTED]

=====

INTRA-OPERATIVE CONSULTATION

A. Brain, right frontal tumor, excision biopsy, touch prep and smears: High histological grade glioma, C/W glioblastoma. [REDACTED] Frozen section performed at [REDACTED] and results reported to the Physician of Record. [REDACTED]

[REDACTED]

GROSS DESCRIPTION

A.
Received fresh, several fragments, 1.2 cm. In aggregate. Soft, tannish-brown, with small blood clot. In total, A1 and A2.

B.
SPECIMEN: Right frontal tumor.
FIXATIVE: Formalin.
GENERAL: A 3.0 x 2.0 x 1.0 cm., 1.36 gm. aggregate of several irregularly shaped red to gray-tan fragments of brain tissue.
SECTIONS: B1, B2 all submitted.

[REDACTED]

MICROSCOPIC DESCRIPTION

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates focal sparse gliofibrillogenesis by the neoplastic cells. The neoplastic cells do not over express the p53 protein. With the MIB-1 there is a proliferation index of about 30% in the more active areas.

ICD-9(s):

191.1 191.9

[REDACTED]

[page 3 of 3]
Histo Data

Part A: Brain, right frontal tumor, excision biopsy

Taken:	Received:	Block	Ordered	Comment
Stain/cnt		1		
FS H/E x 1		1		
H/E x 1		1		
H/E x 1		2		

Part B: Brain, right frontal tumor, excision biopsy

Taken:	Received:	Block	Ordered	Comment
Stain/cnt		1		
mGFAP-DA x 1		1		Please repeat at normal
and lower dilution. Thanks.				
mGFAP-DA x 1		1		
H/E x 1		1		
MGMT x 1		1		
MIB1-DA x 1		1		
P53DO7 x 1		1		
H/E x 1		2		

*** End of Report ***

Source: NCI Genomic Data Commons file 1b5c875c-2eee-43f1-bcc0-feb5d00b1d2d (TCGA-06-0650.DE2D8135-1C15-4475-BE37-232D9779E908.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).